Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5L6, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5L6-01A (Primary Tumor).

ICD-O-3

Carcinoma, adrenal cortical
8370/3

Site ① Adrenal Gland, cortex
C74.0

gnd 2/6/13

Procedure: L adrenalectomy

Gross description: 12.5 x 10.5 x 7cm, 467g

Diagnosis: adrenocortical carcinoma, KI67 5-10%; , pT2 pNx L1 V1 Pn0 R0

Reference Pathology only: none

Weiss score: 7

Hough score: 3.52

Van Slooten score: 22.7

Criteria	hw 1/14/13	Yes	No
UIPAA Discrepancy			

Source: NCI Genomic Data Commons file f491c20c-cf08-4ab6-aff0-0ce96758f423 (TCGA-OR-A5L6.6104CA0C-86CD-46C9-A111-0024A75FB727.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).